Somatic mutation profile of tumor specimen TARGET-30-PAUATG-01A (aliquot TARGET-30-PAUATG-01A-01D) from TARGET case TARGET-30-PAUATG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 10.0 years (3,642 days).
Specimen TARGET-30-PAUATG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e960f614-82bd-480e-9f45-3f55e99af97b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUATG-10A (Blood Derived Normal), aliquot TARGET-30-PAUATG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acae2fa0-fea0-4ee5-a488-e9ecab3af051

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC9 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 145/235 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67785825; called by muse, mutect2, varscan2
- KIT | c.1485C>T p.N495= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs775498908, COSV55422798; ClinVar: likely benign; called by muse, mutect2, varscan2
